Gene-level copy-number profile of tumor specimen HTMCP-03-06-02108-01A from CGCI case HTMCP-03-06-02108, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02108-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f671a34c-b36e-4385-bf6d-d449fd84a4af.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02108-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/eb960949-590b-43aa-aa07-8c26f0b4f13e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 5,881; copy number 2: 44,989; copy number 3: 7,003; copy number 4: 200; copy number 5: 96; copy number 6: 50; copy number 7: 11; copy number 11: 43; copy number 13: 13; copy number 15: 19.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–195,411, 15 genes (within-gene range 0–1): OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2.
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–1): RNA5SP251.
- chr8:7,715,443–8,226,614, 38 genes: FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1.
- chr8:12,115,767–12,436,343, 23 genes (within-gene range 0–1): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2.
- chr21:8,762,386–9,129,752, 12 genes: CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 232 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:16,149,251–16,149,394, 1 gene, copy number 5: AC174048.1.
- chr2:84,031,140–86,106,155, 59 genes, copy number 6–13: CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1, SUCLG1, DNAH6, DUXAP1, LDHAP7, TRABD2A, AC010087.1, RPL12P18, TMSB10, RPS2P17, KCMF1, LINC01964, AC078974.1, LSM3P3, TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68, SFTPB, GNLY, GPR160P1, RNU1-38P, ATOH8, MIR6071, AC105053.1, RN7SKP83, ST3GAL5, ST3GAL5-AS1, AC012511.1, POLR1A.
- chr2:188,974,373–191,425,389, 50 genes, copy number 5–6: COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P.
- chr7:45,157,791–45,186,302, 1 gene, copy number 5: RAMP3.
- chr7:54,185,071–56,055,502, 47 genes, copy number 5–6: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, SNORA22B.
- chr11:69,985,876–71,252,577, 29 genes, copy number 13–15: AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr14:22,197,446–22,482,959, 1 gene, copy number 5 (within-gene range 4–5): AC244502.1.
- chr14:22,265,749–22,503,814, 43 genes, copy number 5: TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.

Autosomal genes at a single copy (total copy number 1): 4,887. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
